Somatic mutation profile of tumor specimen C3L-08169-01 (aliquot CPT0511680006) from CPTAC case C3L-08169, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 64.8 years (23,663 days).
Specimen C3L-08169-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ca399f1-685c-4073-b215-6bdfe8aea784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08169-31 (Blood Derived Normal), aliquot CPT0511670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e735a490-be88-4bb4-a6a8-33c5f26d2ac9

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 122/947 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs371841362, COSV99573838; called by muse, mutect2, varscan2
- ATP1A3 | c.290G>A p.R97Q (on ENST00000545399 / NM_001256214.2; = p.R84Q on NM_152296.5) | Missense Mutation (SNP) | VAF 119/982 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs782194114, COSV57490532; called by muse, mutect2, varscan2
- B3GNT9 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 62/716 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV54629571; called by muse, mutect2
- CHI3L1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 141/521 reads (27%) | catalogued as rs151205460; called by muse, mutect2, varscan2
- CLTC | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs747997399, COSV104393565; called by muse, mutect2, varscan2
- DHX15 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 47/353 reads (13%) | catalogued as rs868164768, COSV100391738; called by muse, mutect2, varscan2
- DHX38 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs147679168; called by muse, mutect2, varscan2
- DSCAML1 | c.301G>A p.V101M (on ENST00000321322; = p.V41M on NM_020693.4) | Missense Mutation (SNP) | VAF 112/855 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs775298739; called by muse, mutect2, varscan2
- ELAVL3 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 108/791 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1185432149; called by muse, mutect2, varscan2
- ERAS | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 486/1366 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs913149474; called by muse, mutect2, varscan2
- ERBB3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 80/658 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs1429784531, COSV57247034, COSV99915945; called by muse, mutect2, varscan2
- GLDC | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs141153261, COSV58679601; called by muse, mutect2, varscan2
- IGSF11 | c.607C>T p.R203W (on ENST00000393775 / NM_001015887.3; = p.R202W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs779100034, COSV61164767; called by muse, mutect2, varscan2
- KAT6B | c.2725G>A p.V909I | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs777249348; called by muse, mutect2
- KIDINS220 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs903767243, COSV56760214; called by muse, mutect2, varscan2
- LAMA1 | c.8735C>G p.S2912* | Nonsense Mutation (SNP) | VAF 64/486 reads (13%) | catalogued as COSV67545822; called by muse, mutect2, varscan2
- LIN28A | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 140/989 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV54261918; called by muse, mutect2, varscan2
- MCM10 | c.2358C>T p.C786= (on ENST00000484800 / NM_182751.3; = p.C785= on NM_018518.5) | Splice Region (SNP) | VAF 36/272 reads (13%) | catalogued as rs536238621; called by muse, varscan2
- OR51A7 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV63787997, COSV63788424; called by muse, mutect2
- PCDH18 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755471100, COSV61271497; called by muse, mutect2, varscan2
- RAB25 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 81/769 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs766504760; called by muse, mutect2, varscan2
- RNPEPL1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 127/901 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.013); catalogued as rs1243250120; called by muse, mutect2, varscan2
- SLC6A1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 95/837 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs766945941; called by muse, mutect2, varscan2
- SLC6A12 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 83/521 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355445068, COSV62884292; called by muse, mutect2, varscan2
- SRGAP1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 90/726 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs377601761; called by muse, mutect2, varscan2
- SULT1C2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372096862; called by muse, mutect2, varscan2
- TNRC18 | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 142/884 reads (16%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1401194174; called by muse, mutect2, varscan2
- TRPC7 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 96/793 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs757025359, COSV61452096, COSV61454267; called by muse, mutect2, varscan2
- TUBG1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 84/495 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs780458781; called by muse, mutect2, varscan2
- VAV1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 70/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs769393831, COSV58382329; called by muse, mutect2, varscan2
- ABCC9 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); called by mutect2, varscan2
- AKAP9 | c.10880_10883del p.T3627Kfs*6 (on ENST00000359028; = p.T3603Kfs*6 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/336 reads (12%) | called by pindel, varscan2
- ANOS1 | c.1859C>A p.T620K | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ARID1A | c.2402dup p.Q802Sfs*15 | Frame Shift Ins (INS) | VAF 70/556 reads (13%) | called by mutect2, pindel, varscan2
- ASCC3 | c.5588A>G p.N1863S | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP1B4 | c.285T>G p.D95E | Missense Mutation (SNP) | VAF 126/1001 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CDH12 | c.1774T>C p.C592R | Missense Mutation (SNP) | VAF 65/505 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP65 | c.4663A>G p.M1555V | Missense Mutation (SNP) | VAF 52/508 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- CHRDL1 | c.1345C>A p.H449N (on ENST00000372045; = p.H455N on NM_145234.4) | Missense Mutation (SNP) | VAF 41/571 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DENND5B | c.1036A>G p.M346V | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- FAM71E1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- GXYLT1 | c.10T>A p.Y4N | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MAOA | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 68/600 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- OR2G3 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 153/585 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PPP1R21 | c.2314-1G>A p.X772_splice (on ENST00000294952 / NM_001135629.3; = p.X761_splice on NM_152994.5) | Splice Site (SNP) | VAF 30/300 reads (10%) | called by muse, mutect2
- PRSS56 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 168/1079 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SCARB2 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 88/604 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SCRT2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 194/795 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC35F1 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOX18 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 140/1158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UGT3A2 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 63/520 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- USP28 | c.2548T>C p.F850L | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ALDH16A1 | c.678C>T p.V226= | Silent (SNP) | VAF 121/906 reads (13%) | catalogued as rs779691525; called by muse, mutect2, varscan2
- DISP3 | c.852C>T p.D284= | Silent (SNP) | VAF 127/904 reads (14%) | catalogued as rs569895406, COSV104397882; called by muse, mutect2, varscan2
- EDRF1 | c.879C>T p.D293= | Silent (SNP) | VAF 54/411 reads (13%) | catalogued as rs368123992; called by muse, mutect2, varscan2
- EHBP1L1 | c.4008G>C p.G1336= | Silent (SNP) | VAF 36/784 reads (5%) | called by muse, mutect2
- LPCAT1 | c.375C>T p.T125= | Silent (SNP) | VAF 95/1326 reads (7%) | catalogued as rs751048754; called by muse, mutect2
- MUC16 | c.29382G>A p.P9794= | Silent (SNP) | VAF 68/467 reads (15%) | called by muse, mutect2, varscan2
- MYO18B | c.7032G>A p.S2344= | Silent (SNP) | VAF 120/698 reads (17%) | catalogued as rs751381115, COSV100122252; called by muse, mutect2, varscan2
- NEFM | c.588C>T p.R196= | Silent (SNP) | VAF 117/949 reads (12%) | catalogued as COSV55331615; called by muse, mutect2, varscan2
- PDHA1 | c.456G>A p.S152= | Silent (SNP) | VAF 157/737 reads (21%) | catalogued as rs1358837850; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF144B | c.675C>T p.N225= | Silent (SNP) | VAF 36/290 reads (12%) | called by muse, mutect2, varscan2
- RP1 | c.4965G>A p.Q1655= | Silent (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- SLC15A3 | c.159C>T p.T53= | Silent (SNP) | VAF 86/980 reads (9%) | catalogued as rs1191622003, COSV99928369; called by muse, mutect2
- TENM4 | c.2046G>T p.V682= | Silent (SNP) | VAF 127/801 reads (16%) | called by muse, mutect2, varscan2
- VTN | c.1389C>T p.R463= | Silent (SNP) | VAF 52/668 reads (8%) | called by muse, mutect2
- ZDHHC1 | c.447C>T p.H149= | Silent (SNP) | VAF 58/592 reads (10%) | called by muse, mutect2, varscan2
- KIF1A | c.2555+979C>T | Intron (SNP) | VAF 113/1034 reads (11%) | catalogued as rs766588776; called by muse, mutect2, varscan2
